Somatic mutation profile of tumor specimen C3N-03210-02 (aliquot CPT0185170006) from CPTAC case C3N-03210, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 51.5 years (18,827 days).
Specimen C3N-03210-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 608f1803-3e11-4e55-add9-73a2f8f023eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03210-31 (Blood Derived Normal), aliquot CPT0185220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fe46fa9-d041-4772-979a-af9b80d4aa27

The open-access MAF lists 135 somatic variants for this specimen: 94 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 24, Intron 11, Nonsense Mutation 11, Frame Shift Del 4, 5'UTR 3, RNA 3, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 99/519 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 137/343 reads (40%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, varscan2
- ABCB4 | c.3739G>C p.D1247H (on ENST00000265723 / NM_018849.3; = p.D1240H on NM_000443.4) | Missense Mutation (SNP) | VAF 101/662 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1384287574; called by muse, mutect2, varscan2
- ABHD4 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs138808701; called by muse, mutect2, varscan2
- ACTN2 | c.775del p.A259Rfs*17 | Frame Shift Del (DEL) | VAF 73/427 reads (17%) | catalogued as COSV63974769, COSV63976641; called by mutect2, pindel, varscan2
- ALPG | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV54967929; called by mutect2, varscan2
- APC | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 8/101 reads (8%) | catalogued as CM127463, COSV57329086, COSV57386299; called by muse, mutect2
- ARHGEF7 | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 27/153 reads (18%) | catalogued as rs1181335787; called by muse, mutect2, varscan2
- BTNL2 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs1451486536; called by muse, mutect2, varscan2
- BTNL9 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 72/578 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs146697971; called by muse, mutect2, varscan2
- CDH7 | c.1667C>A p.S556* | Nonsense Mutation (SNP) | VAF 13/282 reads (5%) | catalogued as COSV59888426; called by muse, mutect2
- CMBL | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1302997309; called by muse, mutect2, varscan2
- CRISP2 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100189183; called by muse, mutect2, varscan2
- DIRAS2 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs552701958, COSV65370882; called by muse, mutect2, varscan2
- ENO4 | c.821C>T p.T274M (on ENST00000622726; = p.T273M on NM_001242699.2) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs763445380, COSV58004207, COSV58005866; called by muse, mutect2, varscan2
- EVC2 | c.3029G>T p.C1010F | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as rs1434900133; called by muse, mutect2, varscan2
- FAT3 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751323947, COSV53117669; called by muse, mutect2, varscan2
- GABRA5 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.078); catalogued as COSV100164895; called by muse, mutect2, varscan2
- GNAS | c.335del p.G112Efs*578 | Frame Shift Del (DEL) | VAF 35/219 reads (16%) | catalogued as COSV100007874; called by mutect2, pindel, varscan2
- GTF3C1 | c.4592G>T p.R1531L | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV62245068; called by muse, mutect2, varscan2
- KCNU1 | c.232G>C p.V78L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs185215022; called by muse, mutect2, varscan2
- KIRREL3 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101585749; called by muse, mutect2, varscan2
- LRP12 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs758111725, COSV52625897; called by muse, mutect2
- MUC2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs761477904; called by muse, mutect2, varscan2
- OR11H2 | c.554C>A p.P185Q (on ENST00000556246; = p.P196Q on NM_001197287.1) | Missense Mutation (SNP) | VAF 50/822 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1315905854, COSV73703680; called by muse, mutect2
- OR5T1 | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100478840; called by muse, mutect2, varscan2
- PBRM1 | c.422G>A p.W141* | Nonsense Mutation (SNP) | VAF 12/126 reads (10%) | catalogued as COSV56262663; called by muse, mutect2
- RAD54L2 | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56577891; called by muse, mutect2, varscan2
- SIDT2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200609591; called by muse, mutect2, varscan2
- SIPA1L2 | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756539708, COSV53392687; called by muse, varscan2
- SLC6A12 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs577163007; called by muse, mutect2, varscan2
- TBX5 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59861649; called by muse, mutect2
- TRAV8-7 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs142738907; called by muse, mutect2, varscan2
- UGT1A7 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs748366826; called by muse, mutect2, varscan2
- VSIR | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs779919795, COSV56489538; called by muse, mutect2
- XPNPEP1 | c.33G>T p.R11S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.765); catalogued as COSV59170423; called by muse, mutect2, varscan2
- ACSF2 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- APC | c.2544del p.D849Ifs*12 | Frame Shift Del (DEL) | VAF 16/173 reads (9%) | called by mutect2, pindel, varscan2
- AQP10 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CACNA1C | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CACNA1H | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- CAMTA2 | c.2416G>C p.A806P | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC141 | c.2461C>A p.H821N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CELF1 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CFHR4 | c.1361C>A p.S454* (on ENST00000367416 / NM_001201551.2; = p.S208* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- CNOT1 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- CPA2 | c.1172T>C p.L391S | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.4367A>T p.Q1456L (on ENST00000297405 / NM_001363185.1; = p.Q1352L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- CUBN | c.8719G>A p.A2907T | Missense Mutation (SNP) | VAF 113/499 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DGKB | c.704T>A p.L235* | Nonsense Mutation (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2
- DMGDH | c.544_546delinsAT p.L182Mfs*17 | Frame Shift Del (DEL) | VAF 33/279 reads (12%) | called by pindel, varscan2*
- DNAH10 | c.1870A>G p.K624E (on ENST00000409039; = p.K563E on NM_207437.3) | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2
- DSG4 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- FGD3 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2
- FRMD1 | c.598T>A p.S200T | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRID2 | c.789+1G>T p.X263_splice | Splice Site (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- GSX2 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HOXD12 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.185); called by muse, mutect2
- HS3ST2 | c.578A>T p.N193I | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGSF21 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KANK1 | c.3295A>T p.T1099S | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- KCNE3 | c.28T>A p.W10R | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- KIAA1549 | c.3010G>T p.G1004C | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRK1 | c.2588G>T p.R863L | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NALCN | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NFATC2 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 73/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NNT | c.3146A>T p.Y1049F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR5AK2 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OR5T2 | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- PCDH15 | c.5041G>A p.D1681N (on ENST00000644397 / NM_001354429.2; = p.D1623N on NM_001142771.2) | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.199); called by muse, mutect2
- PIEZO2 | c.1391A>C p.E464A | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- PRKAA2 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- RAD50 | c.2417A>T p.E806V | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, varscan2
- RIMS2 | c.799C>A p.P267T (on ENST00000666250 / NM_001348490.2; = p.P75T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SDHD | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- SERPINB5 | c.1113A>T p.K371N | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- SETDB2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIPA1L1 | c.4064G>A p.G1355D | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.07); called by muse, mutect2
- SNTG2 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- SORBS1 | c.3670C>A p.P1224T (on ENST00000361941 / NM_001034954.2; = p.P616T on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- SPPL2C | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- STON2 | c.2195T>C p.M732T (on ENST00000649389 / NM_001366849.2; = p.M675T on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SUFU | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- TCTEX1D1 | c.460A>T p.S154C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TENM4 | c.8306G>T p.R2769M | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM200A | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- UNC80 | c.4042C>A p.L1348I | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- USP17L10 | c.562A>T p.K188* | Nonsense Mutation (SNP) | VAF 194/554 reads (35%) | called by muse, mutect2, varscan2
- USP43 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VSTM2B | c.771C>T p.G257= | Splice Region (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- ZBTB46 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ZC3H12B | c.1397T>A p.V466E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZC3H15 | c.570C>G p.N190K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZNF273 | c.1691A>G p.H564R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- APC2 | c.378C>T p.A126= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ATF7 | c.1113A>G p.L371= (on ENST00000548446 / NM_001366555.2; = p.L360= on NM_006856.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/330 reads (11%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2295T>C p.S765= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV61804863; called by muse, mutect2, varscan2
- CDH23 | c.1920G>T p.T640= | Silent (SNP) | VAF 40/327 reads (12%) | catalogued as rs779025760; called by muse, mutect2, varscan2
- CHRM3 | c.1758C>A p.P586= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV55082858; called by muse, varscan2
- COL22A1 | c.3588C>A p.P1196= | Silent (SNP) | VAF 37/178 reads (21%) | called by muse, mutect2, varscan2
- COL25A1 | c.1275C>A p.A425= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV101211618; called by muse, mutect2, varscan2
- CPA5 | c.1003C>A p.R335= | Silent (SNP) | VAF 51/278 reads (18%) | catalogued as COSV62570123; called by muse, varscan2
- DDX3X | c.1284A>T p.S428= (on ENST00000399959; = p.S429= on NM_001356.5) | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- DGKB | c.702C>A p.G234= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV51772133; called by muse, mutect2
- FAM83F | c.984C>T p.A328= | Silent (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- FKBP9 | c.930G>A p.G310= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as rs746459254; called by muse, mutect2, varscan2
- GRIN2C | c.2703C>A p.R901= | Silent (SNP) | VAF 28/418 reads (7%) | catalogued as rs775045954; called by muse, mutect2
- HELZ2 | c.3372G>T p.A1124= (on ENST00000467148 / NM_001037335.2; = p.A555= on NM_033405.3) | Silent (SNP) | VAF 65/242 reads (27%) | called by muse, mutect2, varscan2
- ITPR3 | c.2199G>T p.L733= | Silent (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- NLGN2 | c.813C>G p.V271= | Silent (SNP) | VAF 124/279 reads (44%) | catalogued as COSV100259422; called by muse, mutect2, varscan2
- PCDHA1 | c.321G>A p.E107= | Silent (SNP) | VAF 19/402 reads (5%) | called by muse, mutect2
- RNF145 | c.1779A>G p.L593= (on ENST00000424310 / NM_001199383.2; = p.L621= on NM_144726.2) | Silent (SNP) | VAF 57/325 reads (18%) | called by muse, mutect2, varscan2
- SLC4A1 | c.1134C>T p.L378= | Silent (SNP) | VAF 50/236 reads (21%) | called by muse, mutect2, varscan2
- TENM1 | c.7902G>A p.R2634= | Silent (SNP) | VAF 96/154 reads (62%) | called by muse, mutect2, varscan2
- TEX13C | c.744A>G p.L248= | Silent (SNP) | VAF 82/288 reads (28%) | catalogued as rs1257607317; called by muse, mutect2, varscan2
- TUBA3C | c.681C>A p.L227= | Silent (SNP) | VAF 34/239 reads (14%) | catalogued as COSV67139041; called by muse, mutect2, varscan2
- TUBA4B | c.342C>T p.P114= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- ZAN | c.2007C>A p.T669= | Silent (SNP) | VAF 83/337 reads (25%) | called by muse, mutect2, varscan2
- BRSK2 | c.1227-1933C>A | Intron (SNP) | VAF 58/263 reads (22%) | called by muse, mutect2, varscan2
- DUSP4 | c.433+4364C>A | Intron (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- DUSP4 | c.433+4363G>C | Intron (SNP) | VAF 34/154 reads (22%) | catalogued as rs919089271; called by muse, mutect2, varscan2
- FBLN2 | c.-27G>T | 5'UTR (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.-15del | 5'UTR (DEL) | VAF 12/102 reads (12%) | called by mutect2, varscan2
- MSC-AS1 | n.372A>T | RNA (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- NBPF11 | c.-548-3072C>T | Intron (SNP) | VAF 26/438 reads (6%) | catalogued as rs1487803420; called by muse, mutect2
- OR7D1P | n.364C>T | RNA (SNP) | VAF 37/184 reads (20%) | catalogued as rs533776757; called by muse, mutect2, varscan2
- PLCB4 | c.504-32T>A | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- POU5F1 | c.526+34C>A | Intron (SNP) | VAF 42/174 reads (24%) | called by muse, mutect2, varscan2
- PPFIA3 | c.240+48del | Intron (DEL) | VAF 8/32 reads (25%) | catalogued as rs906895738; called by mutect2, pindel
- PUDP | c.511-7305G>T | Intron (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1227-70C>T | Intron (SNP) | VAF 17/82 reads (21%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.643C>A | RNA (SNP) | VAF 25/460 reads (5%) | called by muse, mutect2
- ZAP70 | c.402+241G>T | Intron (SNP) | VAF 52/336 reads (15%) | called by muse, mutect2, varscan2
- ZBTB17 | c.535+16A>G | Intron (SNP) | VAF 78/321 reads (24%) | called by muse, mutect2, varscan2
- ZNF592 | c.-17C>G | 5'UTR (SNP) | VAF 11/242 reads (5%) | catalogued as rs1158910881; called by muse, mutect2
